Somatic mutation profile of tumor specimen TCGA-FD-A62S-01A (aliquot TCGA-FD-A62S-01A-11D-A30E-08) from TCGA case TCGA-FD-A62S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 60.2 years (22,000 days).
Specimen TCGA-FD-A62S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c51f75c-c0df-40e1-ae7c-53641f4dd80f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A62S-10A (Blood Derived Normal), aliquot TCGA-FD-A62S-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/283fbcba-d874-4f55-af76-185346c0262a

The open-access MAF lists 83 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4241A>G p.Y1414C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325155; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.1313T>C p.I438T | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs61740446, COSV52981685; called by muse, mutect2, varscan2
- ADAMTS3 | c.2341G>T p.G781C | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54401460; called by muse, mutect2, varscan2
- AHNAK2 | c.1154G>C p.R385P | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs374238837, COSV60913733; called by muse, mutect2, varscan2
- ALDOC | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs753185090, COSV52026318, COSV99257195; called by muse, mutect2, varscan2
- ANO4 | c.2078del p.P693Hfs*12 (on ENST00000392977 / NM_001286615.2; = p.P658Hfs*12 on NM_178826.4) | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as COSV54590135; called by mutect2, pindel, varscan2
- ARSD | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54202819; called by muse, mutect2, varscan2
- ASB17 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV52411936; called by muse, mutect2, varscan2
- ATP10A | c.3961C>A p.P1321T | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV100791392, COSV63523387; called by muse, mutect2, varscan2
- C3 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55580655; called by muse, mutect2, varscan2
- CAMSAP1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1475577248, COSV56718533; called by muse, mutect2, varscan2
- CDH13 | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as rs778521715, COSV51825313, COSV51836932; called by muse, mutect2, varscan2
- CSMD3 | c.6521C>A p.T2174N (on ENST00000297405 / NM_001363185.1; = p.T2070N on NM_052900.3) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV52304131, COSV99844367; called by muse, mutect2
- DHX29 | c.4089G>C p.L1363F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52421737, COSV99287042; called by muse, mutect2, varscan2
- DKC1 | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 21/141 reads (15%) | catalogued as COSV101059890; called by muse, mutect2, varscan2
- DLG2 | c.2018C>G p.T673R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV54681404; called by muse, varscan2
- DLL1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV64538705; called by muse, mutect2
- DMD | c.6289G>A p.G2097R | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as rs748694120, COSV63788017; called by muse, mutect2, varscan2
- DMD | c.1648C>A p.R550S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55878039, COSV99922880; called by muse, mutect2, varscan2
- DYNC1H1 | c.10832G>A p.R3611Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs760957660, COSV64141875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESX1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65425069; called by muse, mutect2, varscan2
- EYS | c.524A>C p.Q175P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV60998976; called by mutect2, varscan2
- FAM71B | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs911745462, COSV57229782, COSV57230751; called by muse, mutect2, varscan2
- FBXO34 | c.1400A>C p.Q467P | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58256793; called by muse, mutect2, varscan2
- GPR82 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV56888198; called by muse, mutect2, varscan2
- GTF2IRD1 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV56091391; called by muse, mutect2, varscan2
- HDX | c.176T>A p.M59K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52982436; called by muse, mutect2, varscan2
- HERC1 | c.9896T>C p.V3299A | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV101496734; called by muse, mutect2
- HSPG2 | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375031442; called by muse, mutect2, varscan2
- IRS4 | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV64535736; called by muse, mutect2, varscan2
- KNDC1 | c.3997G>A p.V1333M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100465480, COSV58845357; called by muse, mutect2, varscan2
- LBP | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1223982939, COSV54143314; called by muse, mutect2
- LEPROT | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60757086, COSV60763472; called by muse, mutect2
- MAGEB10 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV63312590; called by muse, mutect2, varscan2
- MED27 | c.635_637del p.T212del | In Frame Del (DEL) | VAF 11/62 reads (18%) | catalogued as rs760314611; called by mutect2, pindel, varscan2
- MYO9B | c.597C>A p.Y199* | Nonsense Mutation (SNP) | VAF 46/263 reads (17%) | catalogued as COSV101261731; called by muse, mutect2, varscan2
- NCOA2 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.363); catalogued as rs778430475, COSV71764707; called by muse, mutect2, varscan2
- NR0B1 | c.362C>G p.P121R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.152); catalogued as COSV66764750; called by muse, mutect2, varscan2
- NXF3 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as rs749173382, COSV67705007; called by muse, mutect2, varscan2
- OBSCN | c.20822C>T p.P6941L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV63345247; called by muse, mutect2, varscan2
- OR5D18 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61738517; called by muse, mutect2, varscan2
- OTOGL | c.1336G>A p.G446S (on ENST00000547103; = p.G437S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs200388065; called by muse, mutect2, varscan2
- PCDH11X | c.3955A>T p.K1319* | Nonsense Mutation (SNP) | VAF 36/226 reads (16%) | catalogued as COSV100013436; called by muse, mutect2, varscan2
- PDE3B | c.1085T>C p.M362T | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs946315738, COSV56390089; called by muse, mutect2, varscan2
- PDHA1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.148); catalogued as COSV63329059; called by muse, mutect2
- PPP4R4 | c.1926G>T p.K642N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV58557889; called by muse, mutect2, varscan2
- PRAMEF12 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as COSV63216604; called by muse, mutect2, varscan2
- PRLR | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV51500197; called by muse, mutect2
- RABGGTB | c.520T>A p.C174S | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60638974; called by muse, mutect2, varscan2
- RGS21 | c.405dup p.L136Tfs*4 | Frame Shift Ins (INS) | VAF 15/73 reads (21%) | catalogued as rs746536278; called by mutect2, pindel, varscan2
- RNF43 | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV68460136; called by muse, mutect2, varscan2
- SETD5 | c.2093A>G p.K698R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100200907; called by muse, mutect2
- SHROOM3 | c.587+1G>A p.X196_splice | Splice Site (SNP) | VAF 42/259 reads (16%) | catalogued as COSV56038529; called by muse, mutect2, varscan2
- SNRPN | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100578297, COSV57599968; called by muse, mutect2
- SYNE1 | c.8062G>T p.G2688W (on ENST00000367255 / NM_182961.4; = p.G2695W on NM_033071.3) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55088750; called by muse, mutect2, varscan2
- TRIM7 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs1269752401, COSV51241973; called by muse, mutect2
- TTN | c.48619C>T p.P16207S (on ENST00000591111; = p.P8783S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | PolyPhen possibly damaging (0.651); catalogued as COSV60313047; called by muse, mutect2, varscan2
- ZCCHC24 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs749127852, COSV64887427; called by muse, mutect2, varscan2
- ZFHX3 | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 54/455 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as COSV51733773; called by muse, mutect2, varscan2
- GRIPAP1 | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- KIR2DL4 | c.728A>G p.Y243C (on ENST00000396284; = p.Y204C on NM_001080770.2) | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OAS2 | c.388del p.Q130Rfs*20 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- ADCY2 | c.2610C>A p.A870= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100603444; called by muse, varscan2
- ALDH3B2 | c.414G>A p.V138= | Silent (SNP) | VAF 221/1220 reads (18%) | catalogued as COSV62429282; called by muse, mutect2, varscan2
- CNNM3 | c.1419G>A p.K473= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV59709907; called by muse, mutect2, varscan2
- COL6A6 | c.5937T>A p.A1979= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV62036151; called by muse, mutect2, varscan2
- DACH2 | c.1017G>A p.Q339= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV64184135; called by muse, mutect2, varscan2
- HHLA2 | c.756A>G p.P252= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs1251115812, COSV63319716; called by muse, mutect2, varscan2
- MDGA1 | c.1017C>T p.D339= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs762274613, COSV99777159; called by muse, mutect2
- MME | c.1809C>T p.L603= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs148809350; called by muse, mutect2, varscan2
- MUC16 | c.38028C>A p.S12676= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV67490397; called by muse, mutect2, varscan2
- PCDHA3 | c.1287C>T p.D429= | Silent (SNP) | VAF 52/253 reads (21%) | catalogued as COSV63543404; called by muse, mutect2, varscan2
- SLC17A8 | c.63G>A p.V21= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV60123267; called by muse, mutect2
- STUB1 | c.265C>T p.L89= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV50203794; called by muse, mutect2, varscan2
- TAF1C | c.1629C>T p.L543= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV58989098; called by muse, mutect2, varscan2
- TBP | c.240G>A p.Q80= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs112748399, COSV57830518; called by muse, varscan2
- TEAD3 | c.621A>G p.S207= | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as COSV58818408; called by muse, mutect2
- TFAP2C | c.1224G>T p.A408= | Silent (SNP) | VAF 44/175 reads (25%) | catalogued as COSV52373039; called by muse, mutect2, varscan2
- ZBTB21 | c.24C>T p.I8= | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as COSV60405595; called by muse, mutect2, varscan2
- FBXL21P | n.1371T>C | RNA (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99778399; called by muse, mutect2
- KCNIP4 | c.61+251200T>A | Intron (SNP) | VAF 9/69 reads (13%) | catalogued as COSV66196190; called by mutect2, varscan2
- SNX5 | c.51+5475A>T | Intron (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100899040; called by muse, mutect2, varscan2
